Somatic mutation profile of tumor specimen 0DVM1I from CCDI case PBCNAR, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 16.3 years (5,956 days).
Specimen 0DVM1I: Tissue type: Tumor; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9791cc2b-02ce-4219-b8ab-ff4b5c2df518.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DVM1U (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/45609835-e591-40ff-a9cc-cb99f6695f7a

The open-access MAF lists 12 somatic variants for this specimen: 8 protein-altering or splice-affecting, 2 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 8, Silent 2, 3'Flank 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- RASA3 | c.959C>T p.A320V | Missense Mutation (SNP) | VAF 120/540 reads (22%) | SIFT tolerated (0.05); PolyPhen benign (0.194); catalogued as rs199737016; called by muse, mutect2, varscan2
- RNF138 | c.553G>C p.V185L | Missense Mutation (SNP) | VAF 27/270 reads (10%) | SIFT tolerated (0.22); PolyPhen benign (0.083); catalogued as COSV55233904; called by muse, mutect2, varscan2
- SSX5 | c.419G>A p.R140H (on ENST00000347757 / NM_175723.1; = p.R181H on NM_021015.4) | Missense Mutation (SNP) | VAF 74/278 reads (27%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs144094801, COSV61254546; called by muse, mutect2, varscan2
- ZIC1 | c.745A>G p.M249V | Missense Mutation (SNP) | VAF 69/340 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.827); catalogued as COSV51550519; called by muse, mutect2, varscan2
- BCL2L13 | c.707G>T p.S236I | Missense Mutation (SNP) | VAF 76/418 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.797); called by mutect2, varscan2
- GTF3C1 | c.4034C>T p.A1345V | Missense Mutation (SNP) | VAF 50/278 reads (18%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.781); called by muse, mutect2, varscan2
- SMPD1 | c.548T>G p.V183G | Missense Mutation (SNP) | VAF 55/292 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.361); called by muse, mutect2, varscan2
- ZNF219 | c.1897G>A p.A633T | Missense Mutation (SNP) | VAF 49/228 reads (21%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- CSMD1 | c.1521G>A p.S507= (on ENST00000520002; = p.S506= on NM_033225.6) | Silent (SNP) | VAF 95/501 reads (19%) | catalogued as rs536408683, COSV68218703; called by muse, mutect2, varscan2
- HRNR | c.5805C>T p.G1935= | Silent (SNP) | VAF 40/1082 reads (4%) | catalogued as rs1454784413; called by muse, mutect2
- JAM2 | c.-95T>C | 5'UTR (SNP) | VAF 6/17 reads (35%) | called by muse, mutect2
- KIR3DL1 | chr19:54832744 C>T | 3'Flank (SNP) | VAF 96/398 reads (24%) | called by muse, mutect2, varscan2
